CCDI case PBBSAI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/9ec3148d-c08d-4dae-b98f-763917d9a5eb

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.8 years (5,051 days).

Biospecimens (3 samples)
- Sample 0DFBLA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFBLC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFBLO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
